Somatic mutation profile of tumor specimen TCGA-A4-A4ZT-01A (aliquot TCGA-A4-A4ZT-01A-11D-A26P-10) from TCGA case TCGA-A4-A4ZT, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.3 years (26,058 days).
Specimen TCGA-A4-A4ZT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69bea7dc-e69c-49cf-b86e-476fccac28b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A4ZT-10A (Blood Derived Normal), aliquot TCGA-A4-A4ZT-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2274af03-f80d-454a-9d2e-419347b2cbd8

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 3, Intron 3, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.891); catalogued as COSV57701626; called by muse, mutect2, varscan2
- ACTB | c.1034T>C p.I345T | Missense Mutation (SNP) | VAF 182/372 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59320205; called by muse, mutect2, varscan2
- AGK | c.1142G>C p.G381A | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs1250667718, COSV62595442; called by muse, mutect2, varscan2
- AIFM2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs376374471; called by muse, mutect2, varscan2
- ANK2 | c.7347C>A p.H2449Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV52177882; called by muse, mutect2, varscan2
- ANKRD34C | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV69854991; called by muse, mutect2, varscan2
- ATP6V1B1 | c.667A>T p.I223F | Missense Mutation (SNP) | VAF 144/255 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52270853; called by muse, mutect2, varscan2
- CAMTA2 | c.3579A>T p.E1193D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV52778617; called by muse, mutect2, varscan2
- CCDC113 | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54687051; called by muse, mutect2, varscan2
- CCDC74A | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV54608442; called by muse, mutect2, varscan2
- CHTF18 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 125/240 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV50101651; called by muse, mutect2, varscan2
- CSMD2 | c.7028A>T p.Q2343L | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV53940502; called by muse, mutect2, varscan2
- DOCK10 | c.3166G>A p.V1056I | Missense Mutation (SNP) | VAF 111/204 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs371861682, COSV51430388; called by muse, mutect2, varscan2
- FERMT3 | c.1739G>T p.R580L (on ENST00000279227 / NM_178443.3; = p.R576L on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV54175007, COSV99655769; called by muse, mutect2, varscan2
- FNDC3B | c.599T>A p.I200N | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV61046852; called by muse, mutect2, varscan2
- H2BC15 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57586190; called by muse, mutect2, varscan2
- IFNAR1 | c.1144-1G>A p.X382_splice | Splice Site (SNP) | VAF 12/16 reads (75%) | catalogued as COSV54253527; called by muse, mutect2
- KRT13 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 143/229 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV55840930; called by muse, mutect2, varscan2
- LASP1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV58805415; called by muse, mutect2
- LIX1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as COSV57207694, COSV57207745; called by muse, mutect2, varscan2
- METTL8 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV64550854; called by muse, mutect2, varscan2
- NUGGC | c.1198A>C p.K400Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV58437523; called by muse, mutect2
- NUGGC | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV58437542; called by muse, mutect2
- NUP188 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs752148727, COSV65363744; called by muse, mutect2, varscan2
- PPP1R10 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278452243, COSV64740024; called by muse, mutect2, varscan2
- PTPRN | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777571269, COSV55350599; called by muse, mutect2, varscan2
- SLFN13 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV53194806; called by muse, mutect2, varscan2
- SMC1B | c.3423C>A p.H1141Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV62529737, COSV62532207; called by muse, mutect2
- SP140L | c.1212T>A p.D404E | Missense Mutation (SNP) | VAF 198/366 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as COSV54746443; called by muse, mutect2, varscan2
- SSH2 | c.3767G>A p.R1256H | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs754211061, COSV52169843; called by muse, mutect2, varscan2
- STXBP3 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64183085; called by muse, mutect2
- TIMELESS | c.3159A>C p.E1053D | Missense Mutation (SNP) | VAF 126/255 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0.011); catalogued as COSV57513810; called by muse, mutect2, varscan2
- TIMM17B | c.501C>G p.S167R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV54431417; called by muse, mutect2, varscan2
- TIMM17B | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54431420; called by muse, mutect2, varscan2
- TRAPPC13 | c.726T>G p.Y242* | Nonsense Mutation (SNP) | VAF 78/213 reads (37%) | catalogued as COSV51559493; called by muse, mutect2, varscan2
- TSHZ2 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61589959, COSV61590259; called by muse, mutect2, varscan2
- TTI1 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.6); catalogued as COSV65062703; called by muse, mutect2, varscan2
- TUBGCP3 | c.2572G>C p.V858L | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.371); catalogued as COSV56189599; called by muse, mutect2, varscan2
- VWA8 | c.4736C>G p.A1579G | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV64998764; called by muse, mutect2, varscan2
- ZNF493 | c.387A>C p.R129S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV62751200; called by muse, mutect2, varscan2
- ZNF564 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as COSV59435982; called by muse, mutect2, varscan2
- ACSS1 | c.397_426del p.D133_T142del | In Frame Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- ANK3 | c.8578_8587delinsT p.A2860_N2863delinsY | In Frame Del (DEL) | VAF 38/102 reads (37%) | called by pindel, varscan2*
- CFAP74 | c.1755_1756del p.K585Nfs*41 | Frame Shift Del (DEL) | VAF 66/212 reads (31%) | called by mutect2, pindel, varscan2
- FNDC7 | c.849_856+15del p.X283_splice | Splice Site (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- MSS51 | c.943del p.T315Lfs*26 | Frame Shift Del (DEL) | VAF 44/128 reads (34%) | called by mutect2, varscan2
- UBA6 | c.595_596insAA p.F199* | Nonsense Mutation (INS) | VAF 27/97 reads (28%) | called by mutect2, pindel*, varscan2*
- UBR4 | c.885_891del p.R296Afs*6 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- AHRR | c.181C>T p.L61= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV57083115, COSV57090941; called by muse, mutect2, varscan2
- CCDC113 | c.489G>T p.G163= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV54687057; called by muse, mutect2, varscan2
- LTK | c.1545C>A p.A515= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as COSV53028715; called by muse, mutect2, varscan2
- METTL8 | c.438T>C p.C146= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV64550868; called by muse, mutect2, varscan2
- OXTR | c.522C>A p.I174= | Silent (SNP) | VAF 98/181 reads (54%) | catalogued as COSV57480254; called by muse, mutect2, varscan2
- PRDM7 | c.969G>T p.R323= | Silent (SNP) | VAF 104/374 reads (28%) | catalogued as COSV57987501; called by muse, mutect2, varscan2
- SCRN2 | c.18T>C p.P6= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as COSV51636900; called by muse, mutect2, varscan2
- SLC6A15 | c.510T>C p.S170= | Silent (SNP) | VAF 56/204 reads (27%) | catalogued as COSV57027090; called by muse, mutect2, varscan2
- SMG1 | c.7068T>C p.N2356= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as COSV67173769; called by muse, mutect2, varscan2
- WDR1 | c.555T>C p.I185= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV53332543; called by muse, mutect2, varscan2
- MACF1 | c.15832-9734C>T | Intron (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57134360; called by muse, mutect2, varscan2
- P2RY1 | c.*29G>A | 3'UTR (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100521799; called by muse, mutect2, varscan2
- SCAF11 | c.219+420C>G | Intron (SNP) | VAF 44/91 reads (48%) | catalogued as rs1306340480; called by muse, mutect2, varscan2
- USP32P3 | n.3271+1163G>T | Intron (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
